Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZO-01A (Primary Tumor).

[page 1 of 4]
1/17/16 lw

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Endometrial adenocarcinoma, endometrioid type, FIGO grade 1 (of 3) is identified forming a mass (3.5 x 3.0 x 1.0 cm) in the uterine fundus (both posterior and anterior). The tumor invades 0.6 cm into the myometrium (total myometrial thickness, 2.0 cm). The tumor does not involve the endocervix. Lymphovascular invasion is not identified. The background endometrium shows complex hyperplasia with atypia. The vaginal cuff margin is negative for tumor [AJCC pT1bNXMX]. The bilateral ovaries and fallopian tubes show no diagnostic abnormalities.

B. C. Lymph nodes, right and left pelvic, excision: Multiple left pelvic lymph nodes (11 right and 7 left) are negative for tumor.

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 100.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa is smooth. There is a 3.5 x 3.0 x 1.0 cm mass in the fundus of the endometrial cavity with 1.5 cm myometrial thickness. There are

[page 2 of 4]
multiple (3) intramural leiomyomas (ranging in size from 0.4 cm to 1.0 cm in greatest dimension). There is a 2.5 x 1.1 x 0.8 cm right ovary with a smooth outer surface and a cut surface with a 6.5 x 0.6 cm right fallopian tube. There is a 2.0 x 1.2 x 0.7 cm left ovary with a smooth outer surface and a solid cut surface with a 6.5 x 0.7 cm left fallopian tube. Representative sections submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a 5.0 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 5.3 x 4.1 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 100.0 gram uterus with attached bilateral tubes and ovaries and an unremarkable cervix. The uterine serosa is smooth. There is a 3.5 x 3.0 x 1.0 cm mass in the fundus of the endometrial cavity with 1.5 cm myometrial thickness. There are multiple (3) intramural leiomyomas (ranging in size from 0.4 cm to 2.0 cm in greatest dimension). There is a 2.5 x 1.1 x 0.8 cm right ovary with a smooth outer surface and a solid cut surface with a 6.5 x 0.6 cm right fallopian tube. There is a 2.0 x 1.2 x 0.7 cm left ovary with a smooth outer surface and a

[page 3 of 4]
solid cut surface with a 6.5 x 0.7 cm left fallopian tube. Representative sections submitted.

B. Received fresh labeled "right pelvic lymph nodes" is a 5.0 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "left pelvic lymph nodes" is a 5.3 x 4.1 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, right and left fallopian tubes and ovaries

- 1 Cervix
- 2 Lower uterine segment
- 3 Tumor
- 4 Tumor
- 5 Tumor
- 6 Tumor
- 7 Serosa
- 8 Right fallopian tube
- 9 Left fallopian tube
- 10 Right ovary
- 11 Left ovary
- 12 Tumor
- 13 Tumor
- 14 Normal endometrium

Part B: Right Pelvic Lymph Nodes

- 1 Right pelvic lns 1
- 2 Right pelvic lns 1
- 3 Right pelvic lns 1
- 4 Right pelvic lns 2
- 5 Right pelvic lns 2
- 6 Right pelvic lns1

Part C: Left Pelvic Lymph Nodes

- 1 Left pelvic lns 3
- 2 Left pelvic lns 2
- 3 Left pelvic lns 3

[page 4 of 4]
4 Left pelvic lns 2
5 Left pelvic lns 1

Source: NCI Genomic Data Commons file e98764b1-1747-47d4-a09a-3e0a809af46e (TCGA-D1-A0ZO.13826E23-2184-4D03-B67C-B312BF4FA87E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).